Gene-level copy-number profile of specimen HCM-CSHL-0808-C55-85A from HCMI case HCM-CSHL-0808-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC2; FIGO stage: Stage IIIC2.
Specimen HCM-CSHL-0808-C55-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be1ef6bc-174b-4eea-b0c0-9c942275e98a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0808-C55-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,274 have no estimate.
https://portal.gdc.cancer.gov/files/19d9bbd3-e992-4d6e-977c-503fe1031479

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 132; copy number 2: 11,238; copy number 3: 23,673; copy number 4: 15,728; copy number 5: 5,819; copy number 6: 1,134; copy number 7: 155; copy number 8: 145; copy number 9: 114; copy number 10: 41; copy number 11: 63; copy number 12: 45; copy number 13: 6; copy number 14: 4; copy number 15: 1; copy number 16: 1; copy number 34: 13.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,816,201–11,771,350, 14 genes: SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr4:181,820,019–181,835,108, 2 genes: TEMN3-AS1, RN7SKP13.
- chr4:181,905,790–181,906,467, 1 gene (within-gene range 0–2): CCNHP1.
- chr14:37,097,062–38,728,481, 20 genes (within-gene range 0–2): AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 588 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,160,083–47,176,921, 1 gene, copy number 7 (within-gene range 6–7): CALM2.
- chr2:66,820,684–67,041,966, 5 genes, copy number 7: DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1.
- chr3:123,282,296–123,449,090, 1 gene, copy number 7 (within-gene range 6–7): ADCY5.
- chr5:15,500,180–16,033,356, 4 genes, copy number 7: FBXL7, CTD-2350J17.1, MIR887, RNA5SP178.
- chr6:11,414,636–11,709,960, 8 genes, copy number 10–11: AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1.
- chr7:44,748,581–45,542,182, 25 genes, copy number 7: ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD, TBRG4, SNORA5A, SNORA5C, SNORA5B, RAMP3, AC073968.2, AC073968.1, ELK1P1, AC073325.1, AC073325.2.
- chr7:45,912,245–47,582,558, 19 genes, copy number 7: IGFBP3, AC073115.2, AC073115.1, FTLP15, TTC4P1, ZNF619P1, AC023669.1, AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, TNS3.
- chr7:48,171,458–53,188,938, 44 genes, copy number 7–8: ABCA13, AC091770.1, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1.
- chr7:54,933,699–55,593,193, 11 genes, copy number 8–9: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3.
- chr7:69,125,270–70,793,506, 9 genes, copy number 8–9: RNU6-832P, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2.
- chr7:76,510,525–76,650,897, 8 genes, copy number 7: UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2.
- chr7:81,489,204–81,770,438, 3 genes, copy number 7: AC008163.1, DDX43P3, HGF.
- chr7:84,983,556–84,984,506, 1 gene, copy number 7: HNRNPA1P8.
- chr7:85,421,122–87,111,282, 8 genes, copy number 7: LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1.
- chr7:87,345,664–87,399,794, 1 gene, copy number 7: CROT.
- chr7:88,420,167–90,211,635, 16 genes, copy number 7–8 (within-gene range 6–8): AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4.
- chr7:91,264,433–100,642,779, 233 genes, copy number 7–11 (broad region; genes not listed).
- chr8:127,578,473–128,564,679, 16 genes, copy number 12: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr11:132,403,360–135,075,908, 38 genes, copy number 7–16: AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr16:29,113,050–29,331,304, 4 genes, copy number 8 (within-gene range 5–8): AC009093.8, AC009093.10, AC009093.2, AC009093.7.
- chr17:39,566,915–39,864,312, 13 genes, copy number 34 (within-gene range 3–34): AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr19:29,205,320–30,038,181, 23 genes, copy number 12: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr22:22,639,177–23,318,037, 67 genes, copy number 9–11 (broad region; genes not listed).
- chr22:46,762,617–49,724,506, 30 genes, copy number 9–11: TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8, Z82202.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1.

Autosomal genes at a single copy (total copy number 1): 132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
